Somatic mutation profile of tumor specimen d109a3c0-350e-47f5-bda0-61899c (aliquot d109a3c0-350e-47f5-bda0-61899c_D6) from CPTAC case 04OV055, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen d109a3c0-350e-47f5-bda0-61899c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bb683db-3647-4e04-9761-7a782cb60c64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 99d3d57c-8487-43c1-9964-5b0f03 (Blood Derived Normal), aliquot 99d3d57c-8487-43c1-9964-5b0f03_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/187afee1-aa2f-42e3-83e9-d2c10e1a22f7

The open-access MAF lists 81 somatic variants for this specimen: 58 protein-altering or splice-affecting, 17 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Intron 6, Frame Shift Del 5, Splice Site 4, Nonsense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 631/816 reads (77%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA2D2 | c.3097A>G p.I1033V (on ENST00000479441 / NM_001174051.3; = p.I1026V on NM_006030.4) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1282276507; called by muse, mutect2, varscan2
- CDR2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV99193514; called by muse, mutect2, varscan2
- CSE1L | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as rs749686049, COSV99521996; called by muse, mutect2, varscan2
- CSMD1 | c.1451+1G>T p.X484_splice (on ENST00000520002; = p.X483_splice on NM_033225.6) | Splice Site (SNP) | VAF 43/66 reads (65%) | catalogued as COSV68193730; called by muse, mutect2, varscan2
- CSRNP1 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 81/289 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs375017149; called by muse, mutect2, varscan2
- CTDSPL | c.685A>G p.I229V (on ENST00000273179 / NM_001008392.2; = p.I218V on NM_005808.3) | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs1293247432; called by muse, mutect2, varscan2
- DGKB | c.1200G>T p.K400N | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1206117395; called by muse, mutect2
- DTX1 | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 114/351 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV55655217; called by muse, mutect2, varscan2
- FBXL5 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 121/364 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV58012687; called by muse, mutect2, varscan2
- FURIN | c.2370C>G p.D790E | Missense Mutation (SNP) | VAF 163/246 reads (66%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.038); catalogued as rs761381371; called by muse, mutect2, varscan2
- HSD17B7 | c.240G>A p.R80= | Splice Region (SNP) | VAF 14/38 reads (37%) | catalogued as rs139465501; called by muse, varscan2
- HUWE1 | c.9058G>A p.E3020K | Missense Mutation (SNP) | VAF 104/811 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99470466, COSV99471613; called by muse, mutect2, varscan2
- LPCAT1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 128/687 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs140317722; called by muse, mutect2, varscan2
- MYH4 | c.2558T>C p.M853T | Missense Mutation (SNP) | VAF 93/137 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as rs1329900263; called by muse, mutect2, varscan2
- NLGN3 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 240/628 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs768259710, COSV100705169; called by muse, mutect2, varscan2
- NR2E3 | c.1193C>G p.T398S | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58908971; called by muse, mutect2, varscan2
- OTX2 | c.640G>A p.G214R (on ENST00000408990 / NM_172337.3; = p.G222R on NM_021728.4) | Missense Mutation (SNP) | VAF 151/349 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs374968145; called by muse, mutect2, varscan2
- RPH3A | c.245G>A p.R82H (on ENST00000389385 / NM_001143854.2; = p.R78H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs141736304, COSV66992865; called by muse, mutect2, varscan2
- SHROOM2 | c.4208C>T p.A1403V | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as rs1174162815; called by muse, mutect2
- SLAMF7 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.312); catalogued as COSV63563173; called by muse, mutect2, varscan2
- SNRPC | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as rs1487538363; called by muse, mutect2, varscan2
- STAC3 | c.997-1G>C p.X333_splice | Splice Site (SNP) | VAF 80/178 reads (45%) | catalogued as rs779483367; called by muse, mutect2, varscan2
- UPK3B | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1176332444; called by muse, mutect2, varscan2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 38/258 reads (15%) | catalogued as rs749830910; called by mutect2, varscan2
- USP51 | c.2025C>A p.D675E | Missense Mutation (SNP) | VAF 115/301 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs112465088; called by muse, mutect2, varscan2
- ZNF517 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 83/553 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs757887551; called by muse, mutect2, varscan2
- AC023055.1 | c.1206A>C p.K402N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAM7 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ARSI | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- BRCA1 | c.2368del p.T790Lfs*2 | Frame Shift Del (DEL) | VAF 109/178 reads (61%) | called by mutect2, pindel, varscan2
- CDK19 | c.433_446del p.N145Qfs*16 | Frame Shift Del (DEL) | VAF 13/27 reads (48%) | called by mutect2, pindel, varscan2
- FARS2 | c.342C>A p.D114E | Missense Mutation (SNP) | VAF 677/2020 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FMO2 | c.37A>C p.S13R | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAK | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 78/133 reads (59%) | called by muse, mutect2, varscan2
- GBP6 | c.983A>T p.Q328L | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- IGKV3-20 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- KIAA1755 | c.2693_2697del p.R898Pfs*41 | Frame Shift Del (DEL) | VAF 143/501 reads (29%) | called by mutect2, pindel, varscan2
- KLHL4 | c.1738G>T p.G580* | Nonsense Mutation (SNP) | VAF 63/204 reads (31%) | called by muse, mutect2, varscan2
- LRP2 | c.10913G>A p.G3638D | Missense Mutation (SNP) | VAF 474/818 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED14 | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MUC16 | c.28393T>G p.S9465A | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MYOM2 | c.1323A>T p.K441N | Missense Mutation (SNP) | VAF 39/375 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- NEUROG1 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 135/162 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP210L | c.2188-2A>T p.X730_splice | Splice Site (SNP) | VAF 47/118 reads (40%) | called by muse, mutect2, varscan2
- OR10V1 | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OTOGL | c.196T>C p.F66L (on ENST00000547103; = p.F57L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAGE5 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 134/374 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLK3 | c.675C>G p.N225K | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRRC2B | c.3752C>G p.T1251R | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2
- RND3 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLITRK4 | c.1808C>A p.P603H | Missense Mutation (SNP) | VAF 117/311 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLX4 | c.1737_1758del p.E581Tfs*36 | Frame Shift Del (DEL) | VAF 60/260 reads (23%) | called by mutect2, pindel, varscan2
- SMG6 | c.3936G>T p.E1312D | Missense Mutation (SNP) | VAF 110/739 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STXBP2 | c.1567A>G p.K523E | Missense Mutation (SNP) | VAF 162/378 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TMF1 | c.3126A>T p.R1042S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- VAV1 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- ZNF296 | c.449-1G>T p.X150_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2
- AFF2 | c.2247C>A p.I749= | Silent (SNP) | VAF 47/361 reads (13%) | catalogued as rs782451155, COSV53980226; called by muse, mutect2, varscan2
- AGO2 | c.810G>A p.T270= | Silent (SNP) | VAF 123/388 reads (32%) | catalogued as rs150148694; called by muse, mutect2, varscan2
- AOC3 | c.465G>C p.V155= | Silent (SNP) | VAF 341/452 reads (75%) | called by muse, mutect2, varscan2
- BCORL1 | c.1389G>T p.V463= | Silent (SNP) | VAF 209/489 reads (43%) | catalogued as rs1468264912; called by muse, mutect2, varscan2
- CHD8 | c.4384C>A p.R1462= (on ENST00000646647 / NM_001170629.2; = p.R1183= on NM_020920.4) | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV63218773; called by muse, mutect2, varscan2
- CYP4V2 | c.705G>A p.K235= | Silent (SNP) | VAF 24/388 reads (6%) | catalogued as rs1333291094; called by muse, mutect2
- EFCAB8 | c.726T>C p.D242= | Silent (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- FER1L5 | c.912G>A p.P304= (on ENST00000623019; = p.P321= on NM_001293083.2) | Silent (SNP) | VAF 40/204 reads (20%) | called by muse, mutect2, varscan2
- HRH3 | c.744C>A p.A248= | Silent (SNP) | VAF 147/295 reads (50%) | called by muse, mutect2, varscan2
- HSD3B1 | c.456C>T p.P152= | Silent (SNP) | VAF 140/417 reads (34%) | catalogued as rs755389773; called by muse, mutect2, varscan2
- PLD3 | c.1086G>C p.L362= | Silent (SNP) | VAF 85/193 reads (44%) | called by muse, mutect2, varscan2
- RTP1 | c.102C>T p.D34= | Silent (SNP) | VAF 103/335 reads (31%) | catalogued as rs771041267; called by muse, mutect2, varscan2
- SHROOM2 | c.4206G>T p.S1402= | Silent (SNP) | VAF 20/182 reads (11%) | called by muse, mutect2
- TTLL7 | c.921A>G p.E307= | Silent (SNP) | VAF 55/83 reads (66%) | called by muse, mutect2, varscan2
- USH2A | c.8478A>G p.P2826= | Silent (SNP) | VAF 126/331 reads (38%) | called by muse, mutect2, varscan2
- USHBP1 | c.1641C>T p.G547= | Silent (SNP) | VAF 83/203 reads (41%) | catalogued as rs747417737; called by muse, mutect2, varscan2
- ZNF831 | c.2784G>C p.V928= | Silent (SNP) | VAF 67/218 reads (31%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+9948G>A | Intron (SNP) | VAF 78/190 reads (41%) | called by muse, mutect2, varscan2
- BPIFA3 | c.537-32G>C | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.1848-1088G>T | Intron (SNP) | VAF 46/159 reads (29%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+494G>A | Intron (SNP) | VAF 130/328 reads (40%) | called by muse, mutect2, varscan2
- LNX1 | c.380+15705C>T | Intron (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
- RPSA | c.498+61C>T | Intron (SNP) | VAF 49/405 reads (12%) | called by muse, mutect2, varscan2
